Surgical pathology report (de-identified scan), TCGA case TCGA-A3-3306, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-A3-3306-01A (Primary Tumor).

[page 1 of 5]
Patient Results Report

Patient Name: [REDACTED]

MR #:

Age: [REDACTED]

Sex: M

[REDACTED] - PATHOLOGY RESULTS (LABORATORY) - Final

Results:

REPORT:

SURGICAL PATHOLOGY REPORT

Patient Name:

Accession #

Med. Rec. #:

Billing Type: Inpatient

Location:

DOB: [REDACTED]

Service: Medicine

Gender: M

Billing:

Physician(s):

Specimen(s) Received

A: Gallbladder

B: Left kidney

C: Spleen and tail of pancreas

Pathologic Diagnosis

A. Gallbladder, cholecystectomy:

- Chronic cholecystitis with cholelithiasis.

B. Kidney, left, nephrectomy:

[page 2 of 5]
[REDACTED]

Patient Results Report

Patient Name:

MR #:

Age:

Sex: M

- Renal cell carcinoma, clear-cell type.
- Firm and nuclear grade 2-3.
- Tumor size: 5.1 cm.
- The tumor is confined to the kidney without extrarenal extension.
- The tumor does not involve the renal pelvis or the renal vein.
- No lymphovascular space invasion is identified.
- Adjacent kidney with benign cortical cyst, 1.5 cm, and mild interstitial chronic inflammation.
- Adrenal gland with no histopathologic abnormality.

C. Spleen and tail of pancreas, excision:

- Accessory spleen.
- Pancreas with no histopathologic abnormality.

PATHOLOGIC STAGE: pT1B pNX pMX.

NOTE: Information on pathology stage and the operative procedure is transmitted to this Institution's Cancer Registry as required for accreditation by the Commission on Cancer. Pathology stage is based solely upon the current tissue specimen, being evaluated, and does not incorporate other relevant data. Pathology stage is only a component to be considered in determining the clinical stage, and should not be confused with nor substituted for it. The exact operative procedure is available in the surgeon's operative report.

Primary Pathologist:

[REDACTED]

[REDACTED]

[page 3 of 5]
[REDACTED]

Patient Results Report

Patient Name: [REDACTED]

MR #:

Age:

Sex: M

Clinical History

Cholecystitis, left kidney suspicious for neoplasm.

Intraoperative Consultation

C. Spleen and tail of pancreas: Accessory spleen identified (microscopic frozen section).

Gross Description

A: Received in formalin labeled "gallbladder" is an 8 x 3 cm gallbladder which is received partially opened. The serosa is tan and diffusely covered with adipose tissue. The cystic duct appears patent. The mucosa is green-brown and velvety and focally denuded near the fundus. Within the lumen of the gallbladder is a 2.5 x 1.5 x 0.5 cm aggregate of nodular black stones, up to 0.5 cm in greatest dimension. The wall is up to 0.1 cm thick. There is up to 0.4 cm of attached adipose tissue. There are no areas suspicious for malignancy identified. Representative sections to include the cystic duct margin are submitted as "A1".

B: Received fresh and placed in formalin labeled "left kidney" is an 883 gram nephrectomy specimen with a copious amount of attached adipose tissue. After removal of the majority of the adipose tissue, the kidney weighs 347 grams and is 15 x 6 x 6 cm. Within the kidney is a 5.1 x 5 x 4.5 cm soft yellow-orange mass which pushes against the capsule. However, the mass does not

[REDACTED]

[page 4 of 5]
Patient Results Report

Patient Name:

MR #:

Age:

Sex: M

appear to extend through the capsule. The mass is near the pelvis of the kidney and questionably involves the pelvis. The renal vein is grossly uninvolved. The mass is variegated with firm white, yellow-orange and red areas identified. The mass is solid with no cystic areas identified. Focally, the mass is calcified. There is a 1.5 cm unilocular subcapsular cyst identified within the kidney. The remaining specimen demonstrates a distinct cortical medullary junction separating a 0.5 cm cortex from a 1.2 cm medulla. There are no additional masses or lesions identified in the remaining renal parenchyma. The urothelium is white-gray and velvety with no masses or lesions identified. Within the attached adipose tissue is a 4.5 x 3 x 0.5 cm adrenal gland which is unremarkable upon sectioning. There are no lymph nodes identified within the adipose tissue.

Block summary: "B1" - vascular and ureteral margins, en face; "B2" - variegated areas of the mass to include the area of calcification; "B3-4" - mass with relationship to the renal pelvis; "B5-6" - mass with relationship to the capsule; "B7" - mass with relationship to adjacent renal parenchyma; "B8" - subcapsular cyst; "B9" - unremarkable renal parenchyma and urothelium; "B10" - representative adrenal gland.

C: Received fresh for frozen section labeled "spleen and tail and pancreas" is a 41 gram specimen consisting of a 5 x 2 x 1.5 cm pancreas, and a 7 x 3 x 1.5 cm spleen. The resection margin of the pancreas is inked black. Sectioning through this specimen demonstrates red-brown splenic parenchyma with a separate discrete 1.6 x 1.6 cm nodule. The splenic parenchyma is diffusely and densely adherent to the pancreatic tissue. The pancreatic tissue is yellow-tan and lobulated. There are no firm masses or areas suspicious for malignancy identified. A representative section through the well-circumscribed portion of the spleen is frozen as "FS-C1", remnant submitted as "C1".

[page 5 of 5]
Patient Results Report

Patient Name:

MR #:

Age:

Sex: M

Additional representative sections to demonstrate the relationship between the pancreatic parenchyma, the well-circumscribed portion of spleen and adjacent splenic parenchyma are submitted in "C2-3". Representative section of the pancreatic tissue to include the black inked resection margin is submitted as "C4".

Microscopic Description

Microscopic examination has been performed on all slides. The pathologic diagnosis encompasses the essential microscopic findings in this case.

Notes:

Current User:

Source: NCI Genomic Data Commons file 50c670e1-51c3-46ae-a771-645dfe72b014 (TCGA-A3-3306.BD7576B9-7FEC-4077-B945-4F0CBAB15FE8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).